Somatic mutation profile of tumor specimen TCGA-87-5896-01A (aliquot TCGA-87-5896-01A-01D-1696-08) from TCGA case TCGA-87-5896, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.4 years (18,391 days).
Specimen TCGA-87-5896-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b134e28-303c-4560-b772-3833cf8d8073.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-87-5896-10A (Blood Derived Normal), aliquot TCGA-87-5896-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e70abc35-c771-4c74-b5b2-c4cbd54928ef

The open-access MAF lists 53 somatic variants for this specimen: 34 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 26, Silent 19, Nonsense Mutation 8.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.3106C>T p.R1036* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as rs748459670, CM062563, COSV61527621; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F9 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); catalogued as rs137852247, CM1314241, CM940587, COSV54378539; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.3413T>G p.F1138C | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65309473; called by muse, mutect2, varscan2
- AK9 | c.4842A>G p.I1614M | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV69848808; called by muse, mutect2, varscan2
- BCOR | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs960778355, COSV60699113; called by muse, mutect2, varscan2
- CACHD1 | c.2738C>T p.T913M | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs182391558, COSV51547812; called by muse, mutect2, varscan2
- CCL2 | c.194T>A p.I65N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56773134; called by muse, mutect2, varscan2
- CSPG4 | c.2577T>G p.Y859* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV57889957; called by muse, mutect2, varscan2
- CUX2 | c.3023G>A p.S1008N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV55623831; called by muse, mutect2, varscan2
- DSP | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.831); catalogued as rs1203795810, COSV65790963; called by muse, mutect2, varscan2
- EDC3 | c.1402G>T p.G468W | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV59338958; called by muse, mutect2, varscan2
- ENPP7 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.516); catalogued as rs868939491, COSV60385219; called by muse, mutect2, varscan2
- EPX | c.1684C>T p.R562* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as rs376157164; called by muse, mutect2, varscan2
- FATE1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.082); catalogued as rs777933414, COSV64848817; called by muse, mutect2, varscan2
- GLT8D2 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.271); catalogued as rs373952967; called by muse, mutect2, varscan2
- GPR149 | c.1366A>G p.I456V | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1194310422, COSV67665613; called by muse, mutect2, varscan2
- GSTA1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 103/278 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as rs374431368; called by muse, mutect2
- HYDIN | c.9166G>A p.D3056N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); catalogued as COSV99992275; called by muse, varscan2
- ITIH6 | c.2634C>A p.N878K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as rs774773302, COSV54486244, COSV54492885; called by muse, mutect2, varscan2
- KTI12 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs778612379, COSV65405558; called by muse, mutect2, varscan2
- MAP4K4 | c.227A>T p.Y76F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV56324517; called by muse, mutect2, varscan2
- MGAT2 | c.1086G>A p.W362* | Nonsense Mutation (SNP) | VAF 45/122 reads (37%) | catalogued as rs1454642029, COSV53565568; called by muse, mutect2, varscan2
- MIOS | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV60766738; called by muse, mutect2, varscan2
- MYBL1 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV72918700; called by muse, mutect2, varscan2
- NOL8 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs867066464, COSV62633992; called by muse, mutect2, varscan2
- ODF2L | c.137A>T p.E46V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV54013135; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.385T>C p.S129P (on ENST00000374531 / NM_001037293.2; = p.S127P on NM_007203.5) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.478); catalogued as COSV57111433; called by muse, mutect2, varscan2
- PGR | c.131C>A p.T44N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); catalogued as rs141862537, COSV54795816; called by muse, mutect2, varscan2
- RAP2C | c.412T>G p.W138G | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61683061; called by muse, mutect2, varscan2
- RPF1 | c.773C>G p.S258* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV65705712; called by muse, mutect2, varscan2
- SI | c.4510C>T p.R1504* | Nonsense Mutation (SNP) | VAF 38/96 reads (40%) | catalogued as rs1164456060, COSV52265207; called by muse, mutect2, varscan2
- TNIK | c.3275A>C p.D1092A | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV52672809; called by muse, mutect2, varscan2
- UBR1 | c.4256A>T p.D1419V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as COSV51925793; called by muse, mutect2, varscan2
- ZP4 | c.1265T>G p.F422C | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63910799; called by muse, mutect2, varscan2
- ABCA13 | c.12183G>T p.L4061= | Silent (SNP) | VAF 54/206 reads (26%) | catalogued as COSV71283052; called by muse, mutect2, varscan2
- CEACAM3 | c.126G>A p.P42= | Silent (SNP) | VAF 45/146 reads (31%) | catalogued as rs782786265, COSV55760722, COSV55762464; called by muse, mutect2, varscan2
- EPHB6 | c.1956C>T p.Y652= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs754417479, COSV63890321, COSV63893851; called by muse, mutect2, varscan2
- FYB1 | c.1155G>A p.T385= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs375737931; called by muse, mutect2, varscan2
- KRTDAP | c.153C>T p.I51= | Silent (SNP) | VAF 43/188 reads (23%) | catalogued as rs376125312; called by muse, mutect2, varscan2
- LAMA1 | c.6219C>T p.D2073= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs751773541, COSV67531675; called by muse, mutect2, varscan2
- MAP7D2 | c.417G>A p.Q139= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV65525523; called by muse, varscan2
- POM121L12 | c.684C>A p.S228= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV68692170, COSV68694065; called by muse, mutect2, varscan2
- PSG1 | c.9C>A p.T3= | Silent (SNP) | VAF 41/165 reads (25%) | catalogued as COSV54944119; called by muse, mutect2, varscan2
- PTPRS | c.336G>A p.S112= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs528468686, COSV53609197; called by muse, mutect2, varscan2
- RHOXF1 | c.546C>T p.V182= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs145568775, COSV54294094; called by muse, mutect2, varscan2
- S100A7L2 | c.291C>T p.S97= | Silent (SNP) | VAF 107/262 reads (41%) | catalogued as rs568882807, COSV64194750; called by muse, mutect2, varscan2
- SGCA | c.723C>T p.R241= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs750636856, COSV56248154; called by muse, mutect2, varscan2
- SIPA1L3 | c.2976C>T p.D992= | Silent (SNP) | VAF 61/122 reads (50%) | catalogued as COSV55908470; called by muse, mutect2, varscan2
- SPG7 | c.1116G>A p.V372= (on ENST00000268704; = p.V379= on NM_003119.4) | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV51947509; called by muse, mutect2, varscan2
- ST6GAL2 | c.237G>A p.A79= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV64525920; called by muse, mutect2, varscan2
- TNS4 | c.1323C>T p.F441= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs1474969360, COSV54183267; called by muse, mutect2, varscan2
- TRAPPC12 | c.678C>T p.S226= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs189855582, COSV60844961; called by muse, mutect2, varscan2
- ZXDA | c.1530C>T p.F510= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV62387392; called by muse, mutect2, varscan2
